Somatic mutation profile of tumor specimen TCGA-SL-A6J9-01A (aliquot TCGA-SL-A6J9-01A-11D-A31U-09) from TCGA case TCGA-SL-A6J9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.1 years (26,701 days).
Specimen TCGA-SL-A6J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 703fdff4-3563-4466-97f5-9260d6e982dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SL-A6J9-10A (Blood Derived Normal), aliquot TCGA-SL-A6J9-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8176e5e3-cf43-4113-ab35-5a47ec0d7069

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- AHCY | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV99464439; called by muse, mutect2, varscan2
- AMY2B | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100796465; called by muse, mutect2, varscan2
- C5orf34 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100175579; called by muse, mutect2, varscan2
- CNTLN | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99265405; called by muse, mutect2, varscan2
- DDX3X | c.1154C>G p.P385R (on ENST00000399959; = p.P386R on NM_001356.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101302506; called by muse, mutect2, varscan2
- DYRK1A | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100118223; called by muse, mutect2
- EEPD1 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759905183, COSV99632941; called by muse, mutect2, varscan2
- EPB41 | c.1598G>A p.R533H (on ENST00000343067 / NM_001166005.2; = p.R324H on NM_004437.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372946232; called by mutect2, varscan2
- EPG5 | c.2541C>G p.D847E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV99957956; called by muse, mutect2, varscan2
- ERBIN | c.1902dup p.D635Rfs*2 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | catalogued as rs1221795699; called by mutect2, pindel, varscan2
- HMGN5 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100815003; called by muse, mutect2, varscan2
- ID1 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV101076825; called by muse, mutect2, varscan2
- IFRD1 | c.109A>C p.N37H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99134323; called by muse, mutect2, varscan2
- JPH3 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs375230129; called by muse, mutect2, varscan2
- KIRREL3 | c.2297C>A p.P766H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101375222; called by muse, mutect2, varscan2
- KLHL3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100553504; called by muse, mutect2, varscan2
- LRRN4 | c.2215G>A p.V739I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1301411168, COSV101125516; called by muse, mutect2, varscan2
- MAP7D1 | c.1051C>G p.R351G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100294756; called by muse, varscan2
- NAV3 | c.2637C>G p.S879R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1298895487, COSV99894756; called by muse, mutect2, varscan2
- PAIP2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs779602855, COSV99497373; called by muse, mutect2, varscan2
- PRPF18 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187235; called by muse, mutect2, varscan2
- PTPN6 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100017254; called by muse, mutect2, varscan2
- RAET1E | c.460A>T p.N154Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100593519; called by muse, mutect2, varscan2
- REPIN1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.105); catalogued as COSV101262682; called by mutect2, varscan2
- RSF1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV100407791; called by muse, mutect2, varscan2
- SGCG | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54570335, COSV99523342; called by muse, mutect2, varscan2
- STEAP2 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99840646; called by muse, mutect2, varscan2
- TBC1D24 | c.1289G>A p.C430Y (on ENST00000646147 / NM_001199107.2; = p.C424Y on NM_020705.3) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99565249; called by muse, mutect2, varscan2
- TCERG1L | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100894518; called by muse, mutect2, varscan2
- THPO | c.820C>T p.P274S (on ENST00000649095 / NM_001290003.1; = p.P134S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99201226; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TP53I11 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100370973; called by muse, mutect2
- TTC14 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99932313; called by muse, mutect2, varscan2
- UCP2 | c.852C>A p.N284K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60105135; called by muse, mutect2, varscan2
- WDR27 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as rs763131368, COSV61205361, COSV61207713; called by muse, mutect2, varscan2
- ZNF107 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs750758326, COSV100788491, COSV61329253; called by muse, mutect2, varscan2
- TBC1D4 | c.3806_3812del p.L1269Rfs*4 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.12729G>A p.L4243= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100318758; called by muse, mutect2, varscan2
- ANKRD2 | c.510C>T p.D170= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53967597; called by muse, mutect2, varscan2
- ARHGEF10 | c.432T>C p.H144= (on ENST00000398564; = p.H120= on NM_014629.4) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs779284070, COSV100035459; called by muse, mutect2
- CDC42EP4 | c.321G>A p.R107= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100231964; called by muse, mutect2, varscan2
- DSE | c.783T>C p.Y261= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100528770; called by muse, mutect2, varscan2
- MUC16 | c.43512G>A p.E14504= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV101110061; called by muse, mutect2, varscan2
- PRSS57 | c.387C>T p.N129= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs529103659, COSV99383937; called by muse, mutect2, varscan2
- RIOX2 | c.1356G>A p.L452= (on ENST00000333396 / NM_001042533.2; = p.L451= on NM_032778.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1316311838, COSV99477385; called by muse, mutect2, varscan2
- RP1 | c.129C>T p.S43= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1426147835, COSV55118873; called by muse, mutect2, varscan2
- TCEAL3 | c.36G>A p.L12= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99685330; called by muse, mutect2, varscan2
- TUBA3C | c.540C>T p.A180= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs767587440, COSV101262826; called by muse, mutect2, varscan2
- ZNF347 | c.2346G>A p.R782= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs1325242630, COSV100498406; called by muse, mutect2, varscan2
- ZNF574 | c.1365G>A p.E455= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99726441; called by muse, mutect2, varscan2
- EEF1A1P22 | n.73G>A | RNA (SNP) | VAF 8/74 reads (11%) | catalogued as rs777603390; called by muse, mutect2, varscan2
- EPHB2 | c.62-6217G>C | Intron (SNP) | VAF 22/129 reads (17%) | catalogued as COSV101007355; called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3383044 C>T | 3'Flank (SNP) | VAF 56/90 reads (62%) | catalogued as COSV100514520; called by muse, mutect2, varscan2
